CGCI case BLGSP-71-19-00133 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd25db19-92dd-4d8e-8b07-4dba8095cfcb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 286 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.4 years (5,607 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 285 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Mediastinal soft tissue; Sites of involvement: Bone, NOS / Bone marrow / Cerebrospinal fluid / Pancreas, NOS / Small intestine / Kidney, NOS / Testes / Mediastinal soft tissue / Peritoneum, NOS / Omentum.
   Pathology details: Bone marrow malignant cells: Yes; Tumor largest dimension diameter: 9.5 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 285 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD19 (IHC): Positive.
- CD20 (IHC): Positive.
- CD22 (IHC): Positive.
- CD3 (IHC): Negative.
- CD33 (IHC): Positive.
- CD34 (IHC): Positive.
- CD45 (IHC): Positive.
- CD7 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Test (IHC): Positive; Specialized molecular test: CD13.
- Test (IHC): Positive; Specialized molecular test: CD4.
- Test (IHC): Positive; Specialized molecular test: surface Ig Kappa.
- Lactate Dehydrogenase 532.

Other clinical attributes
- Day 0: Weight: 97 kg.

Biospecimens (3 samples)
- Sample BLGSP-71-19-00133-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00133-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 1 day; Method of sample procurement: Aspirate; Tissue collection type: Retrospective.
- Sample BLGSP-71-19-00133-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 220 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt's NOS; Extranodal site involvement: 10; Extranodal involvment other: omentum and peritoneal; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: needle biopsy; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 532; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD34, CD45, CD19, CD22, slg kappa, CD4, CD7, CD13, CD33.
